Gene-level copy-number profile of tumor specimen TCGA-BB-4224-01A from TCGA case TCGA-BB-4224, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 52.3 years (19,119 days).
Specimen TCGA-BB-4224-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b37ea112-340e-4613-8514-d8a8bd47410f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-4224-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/77a586f4-48cf-4327-9453-77fae9809dbd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 117; copy number 2: 13,566; copy number 3: 30,649; copy number 4: 8,130; copy number 5: 4,096; copy number 6: 2,340; copy number 7: 264; copy number 8: 426; copy number 9: 128; copy number 10: 30; copy number 14: 38; copy number 19: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BB-4224-01A-01D-1432-01): tumor purity 0.74, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:50,795,120–51,845,628, 17 genes: MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 896 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:102,099,244–103,630,912, 8 genes, copy number 8 (within-gene range 3–8): ZPLD1, AC063938.1, RNU6-461P, RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11.
- chr7:42,954,135–57,837,046, 336 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:37,405,439–41,032,998, 89 genes, copy number 9–19 (broad region; genes not listed).
- chr8:62,248,591–63,014,000, 1 gene, copy number 9 (within-gene range 6–9): NKAIN3.
- chr8:62,658,343–65,184,210, 36 genes, copy number 9: AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251.
- chr8:81,439,436–81,759,515, 16 genes, copy number 9: AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C.
- chr9:30,773,464–31,645,160, 11 genes, copy number 8: KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr9:33,775,183–33,818,795, 1 gene, copy number 7 (within-gene range 2–7): UBE2R2-AS1.
- chr9:33,817,160–36,014,623, 120 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr11:44,539,778–46,739,506, 61 genes, copy number 8–10 (broad region; genes not listed).
- chr11:46,753,125–46,762,499, 3 genes, copy number 10: MIR5582, AC115088.1, SNORD67.
- chr18:20,946,906–29,361,963, 143 genes, copy number 7 (broad region; genes not listed).
- chr20:30,484,925–31,723,989, 34 genes, copy number 9: 5_8S_rRNA, AC018688.1, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1.
- chr20:32,819,954–33,913,336, 37 genes, copy number 8: MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2.

Autosomal genes at a single copy (total copy number 1): 117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
